Somatic mutation profile of tumor specimen C3L-07165-01 (aliquot CPT0461780006) from CPTAC case C3L-07165, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 70.1 years (25,619 days).
Specimen C3L-07165-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7913851-ffc2-4868-974a-b4a35d198833.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07165-71 (Blood Derived Normal), aliquot CPT0460720002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04f66432-a6e3-4f2f-abf9-615c0c7a17a3

The open-access MAF lists 1,337 somatic variants for this specimen: 1,012 protein-altering or splice-affecting, 277 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 732, Silent 277, Frame Shift Del 197, Frame Shift Ins 35, Nonsense Mutation 31, Intron 27, 3'Flank 8, Splice Region 7, Splice Site 5, 3'UTR 5, 5'Flank 4, 5'UTR 3.

Variants (750 of 1,337; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 54/244 reads (22%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, varscan2
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 60/365 reads (16%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FGF16 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 63/339 reads (19%) | catalogued as rs587777050, CM137753, COSV101466309; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NKX6-2 | c.234del p.L79Cfs*109 | Frame Shift Del (DEL) | VAF 50/376 reads (13%) | catalogued as rs765650727; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SCN1A | c.2665del p.A889Lfs*5 (on ENST00000303395 / NM_001202435.3; = p.A878Lfs*5 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 49/288 reads (17%) | catalogued as rs1559200672, COSV57667692; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TCF4 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1568303352, CM091864, COSV61890423; ClinVar: pathogenic; called by muse, varscan2
- USP9X | c.7440dup p.A2481Sfs*17 | Frame Shift Ins (INS) | VAF 57/388 reads (15%) | catalogued as rs774054468; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, varscan2
- AAAS | c.771del p.R258Gfs*33 | Frame Shift Del (DEL) | VAF 67/525 reads (13%) | catalogued as rs1184877278, CD067140; called by mutect2, pindel, varscan2
- ABCC12 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 58/440 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs781700815; called by muse, mutect2, varscan2
- ABCF2-H2BE1 | c.818+1G>A p.X273_splice | Splice Site (SNP) | VAF 42/238 reads (18%) | catalogued as rs1450672718, COSV99734589; called by muse, mutect2, varscan2
- ABLIM2 | c.354del p.D120Tfs*3 | Frame Shift Del (DEL) | VAF 30/232 reads (13%) | catalogued as rs749606695; called by mutect2, pindel, varscan2
- AC109583.1 | c.28C>A p.R10S | Missense Mutation (SNP) | VAF 26/383 reads (7%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); catalogued as COSV59351028; called by muse, mutect2
- ACHE | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 83/561 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99574178; called by muse, mutect2, varscan2
- ACP7 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 27/595 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs1199368105, COSV58700675; called by muse, mutect2
- ACSL6 | c.215G>A p.R72Q (on ENST00000379240; = p.R97Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.897); catalogued as rs769658964; called by muse, varscan2
- ACVR2B | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 70/376 reads (19%) | catalogued as COSV61702334; called by muse, mutect2, varscan2
- ADAM29 | c.2101del p.S701Vfs*4 | Frame Shift Del (DEL) | VAF 28/212 reads (13%) | catalogued as rs34732497, COSV63661841; called by mutect2, varscan2
- ADAM33 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 72/343 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs779317899, COSV62933451; called by muse, mutect2, varscan2
- ADAMTS1 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 68/334 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.354); catalogued as rs532454101; called by muse, mutect2, varscan2
- ADAMTS12 | c.2298G>T p.K766N | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV61261944; called by muse, mutect2, varscan2
- ADAMTS12 | c.881T>C p.V294A | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.1); catalogued as rs762540842; called by muse, mutect2, varscan2
- ADCK1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs757237522, COSV53082582; called by muse, mutect2, varscan2
- ADRA1B | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1396771876; called by mutect2, varscan2
- AGAP3 | c.1639C>T p.R547W (on ENST00000622464; = p.R583W on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/437 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1196583968, COSV68243067, COSV68246018; called by muse, mutect2, varscan2
- AICDA | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 73/391 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV57563759; called by muse, mutect2, varscan2
- AKAP6 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 84/443 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371976640; called by muse, mutect2, varscan2
- AKR7A2 | c.467G>A p.C156Y | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746942815; called by muse, mutect2, varscan2
- ALG1L2 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 18/319 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs1450800688; called by muse, mutect2
- ALOX12B | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 27/384 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs1308351316, COSV59877337; called by muse, mutect2
- ALPK1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765776944; called by muse, mutect2
- AMH | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 71/419 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as rs777178028; called by muse, mutect2, varscan2
- AMPD1 | c.773G>A p.S258N | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100815218; called by muse, mutect2
- ANKRD11 | c.4609G>A p.G1537S | Missense Mutation (SNP) | VAF 69/432 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1347006212, COSV56375233; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- AOC2 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 24/419 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1489340926; called by muse, mutect2
- AP3M2 | c.227del p.P76Lfs*26 | Frame Shift Del (DEL) | VAF 77/424 reads (18%) | catalogued as rs759247606, COSV51528744; called by mutect2, pindel, varscan2
- APBB3 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 77/512 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as COSV60051491; called by muse, mutect2, varscan2
- APOOL | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 25/563 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV100920872; called by muse, mutect2
- ARAP1 | c.3479G>A p.R1160H (on ENST00000393609 / NM_001040118.2; = p.R915H on NM_015242.4) | Missense Mutation (SNP) | VAF 66/415 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs781671391, COSV100501493, COSV61993603; called by muse, mutect2, varscan2
- ARHGAP18 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 64/372 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs772736255; called by muse, mutect2, varscan2
- ARHGAP30 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 84/512 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV63516085; called by muse, mutect2, varscan2
- ARHGAP39 | c.2528C>T p.A843V (on ENST00000276826 / NM_001308208.2; = p.A874V on NM_025251.2) | Missense Mutation (SNP) | VAF 22/459 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1334771312, COSV52769615; called by muse, mutect2
- ARHGAP39 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 96/581 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs1446729819; called by muse, mutect2, varscan2
- ARHGEF10 | c.3245C>T p.A1082V (on ENST00000398564; = p.A1057V on NM_014629.4) | Missense Mutation (SNP) | VAF 70/545 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs777115859; called by muse, mutect2, varscan2
- ARHGEF15 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 56/397 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); catalogued as rs146482304, COSV104423227; called by muse, mutect2, varscan2
- ARHGEF15 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 61/426 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1242591415, COSV62725357; called by muse, mutect2, varscan2
- ARHGEF16 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 58/449 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs977683455; called by muse, mutect2, varscan2
- ARHGEF26 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 72/487 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.333); catalogued as rs1197711696, COSV62852255; called by muse, mutect2, varscan2
- ARID1A | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 66/358 reads (18%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.082); catalogued as rs1169582817; called by mutect2, varscan2
- ARID1A | c.4534C>T p.Q1512* | Nonsense Mutation (SNP) | VAF 83/394 reads (21%) | catalogued as COSV61373983; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 81/442 reads (18%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 52/259 reads (20%) | catalogued as rs776520069; called by mutect2, varscan2
- ARSL | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 73/441 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as rs750673516, COSV66966069; called by muse, mutect2, varscan2
- ART4 | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 58/356 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as COSV57451679; called by mutect2, varscan2
- ASH1L | c.5018G>A p.R1673Q | Missense Mutation (SNP) | VAF 69/356 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs747601173; called by muse, mutect2, varscan2
- ASXL2 | c.2219C>T p.T740M | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV55454297, COSV55456742; called by muse, mutect2
- ATF7 | c.1475C>T p.A492V (on ENST00000548446 / NM_001366555.2; = p.A481V on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs369186071; called by muse, mutect2, varscan2
- ATP13A2 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 64/323 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs113105667; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A3 | c.1174G>A p.A392T (on ENST00000545399 / NM_001256214.2; = p.A379T on NM_152296.5) | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV57488799; called by muse, mutect2, varscan2
- ATP2B1 | c.3304C>T p.R1102C | Missense Mutation (SNP) | VAF 52/482 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV53806213, COSV99665778; called by muse, mutect2, varscan2
- ATP2B3 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 39/617 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1280847735; called by muse, mutect2
- ATP6V0A1 | c.2246C>T p.A749V (on ENST00000343619 / NM_001378531.1; = p.A743V on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1332649860; called by muse, mutect2, varscan2
- ATP8B3 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 67/386 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs533209157, COSV59542307; called by muse, mutect2, varscan2
- ATXN2 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.269); catalogued as rs1465546289; called by muse, mutect2, varscan2
- B3GAT2 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 54/332 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as rs1252525392, COSV100017163, COSV57638347; called by muse, varscan2
- B3GNT2 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 64/459 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs767688621, COSV57343883; called by muse, mutect2, varscan2
- B3GNT6 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 63/435 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs1404965395; called by muse, mutect2, varscan2
- BAHCC1 | c.2053C>A p.R685S | Missense Mutation (SNP) | VAF 77/472 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV57032329; called by muse, mutect2, varscan2
- BCL6B | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 18/453 reads (4%) | catalogued as COSV99546442, COSV99546768; called by muse, mutect2
- BCL9 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 32/500 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs782766696; called by muse, mutect2
- BDH1 | c.685del p.L229Wfs*3 | Frame Shift Del (DEL) | VAF 126/701 reads (18%) | catalogued as rs1002260866; called by mutect2, pindel, varscan2
- BECN2 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.388); catalogued as rs1477670855, COSV61560383; called by muse, mutect2
- BICD2 | c.1964G>A p.R655H | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs143242735; called by muse, mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 44/481 reads (9%) | catalogued as rs776003776; called by mutect2, pindel
- BMP8B | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 13/381 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1196278490; called by muse, mutect2
- BMPER | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 69/487 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51817390; called by muse, mutect2, varscan2
- BMPR2 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as CD061369; called by muse, mutect2
- BNIP5 | c.1702dup p.Y568Lfs*24 | Frame Shift Ins (INS) | VAF 56/269 reads (21%) | catalogued as rs747868798; called by mutect2, varscan2
- C12orf40 | c.18del p.S7Pfs*6 | Frame Shift Del (DEL) | VAF 72/365 reads (20%) | catalogued as COSV61129099; called by mutect2, varscan2
- C13orf42 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1391496221; called by muse, mutect2
- C19orf47 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1237558599, COSV63508893, COSV63508980; called by muse, mutect2
- C19orf67 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 46/490 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs953831709; called by muse, mutect2
- C20orf27 | c.437G>A p.G146D (on ENST00000379772 / NM_001258429.2; = p.G171D on NM_001039140.3) | Missense Mutation (SNP) | VAF 59/386 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360183508; called by muse, mutect2, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 42/385 reads (11%) | catalogued as rs763603775; called by mutect2, pindel
- CACNA1C | c.5177G>A p.R1726H | Missense Mutation (SNP) | VAF 85/415 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs377564636; called by muse, mutect2, varscan2
- CAMSAP1 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 58/411 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as rs767132170; called by muse, mutect2, varscan2
- CAND2 | c.1054C>T p.R352C (on ENST00000456430 / NM_001162499.2; = p.R259C on NM_012298.3) | Missense Mutation (SNP) | VAF 87/408 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755379183, COSV99928475, COSV99928782; called by muse, mutect2, varscan2
- CAPN14 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs773338913; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 46/264 reads (17%) | catalogued as rs762770988, COSV62756627; called by pindel, varscan2
- CAST | c.387dup p.E130Rfs*12 (on ENST00000341926; = p.E213Rfs*12 on NM_001750.7 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 33/227 reads (15%) | catalogued as rs750937315; called by mutect2, varscan2
- CBX4 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 112/544 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.054); catalogued as rs756120158; called by muse, varscan2
- CBY1 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 62/356 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as rs1423977192, COSV53263995; called by muse, mutect2, varscan2
- CBY2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs540448583, COSV60118895; called by muse, mutect2, varscan2
- CCDC116 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 85/522 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.534); catalogued as COSV53037565; called by muse, mutect2, varscan2
- CCDC88C | c.2969C>T p.A990V | Missense Mutation (SNP) | VAF 75/352 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs201174781; called by muse, mutect2, varscan2
- CCER1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 45/672 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62646717; called by muse, mutect2
- CD80 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 55/389 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767373131, COSV51801822; called by muse, mutect2, varscan2
- CDCP1 | c.1927T>C p.C643R | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1373127443; called by muse, mutect2, varscan2
- CDH22 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 46/560 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs774418956; called by muse, mutect2
- CELF6 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs1181691326; called by muse, mutect2, varscan2
- CELSR3 | c.4567A>G p.S1523G | Missense Mutation (SNP) | VAF 76/434 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1309459387; called by mutect2, varscan2
- CEP170B | c.3724A>G p.S1242G (on ENST00000453495; = p.S1171G on NM_015005.3) | Missense Mutation (SNP) | VAF 68/366 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.113); catalogued as rs1421310703; called by muse, mutect2
- CEP170B | c.4339G>A p.A1447T (on ENST00000453495; = p.A1376T on NM_015005.3) | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as rs370907661; called by muse, mutect2, varscan2
- CEP192 | c.2867G>A p.R956H | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs752095796, COSV58061853; called by muse, mutect2, varscan2
- CFAP410 | c.441_444del p.E148Afs*13 | Frame Shift Del (DEL) | VAF 56/437 reads (13%) | catalogued as rs756970705; called by mutect2, pindel, varscan2
- CFAP44 | c.4667G>A p.R1556Q | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs888438654, COSV57662209; called by muse, mutect2, varscan2
- CFAP61 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 88/446 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.668); catalogued as rs775249537, COSV55630430; called by muse, mutect2, varscan2
- CHD4 | c.3163C>T p.R1055C (on ENST00000357008 / NM_001363606.2; = p.R1068C on NM_001273.5) | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894255; called by muse, mutect2, varscan2
- CHD7 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 37/570 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.096); catalogued as rs779024959, COSV104435789; called by muse, mutect2
- CHRM4 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 62/438 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs201805055; called by mutect2, varscan2
- CHRNA10 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 54/359 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763121060, COSV51703869; called by muse, mutect2, varscan2
- CHRNA2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 34/504 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769273715; called by muse, mutect2
- CHRNB3 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 76/509 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1451548832, COSV51493106; called by muse, mutect2, varscan2
- CLCA4 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 52/372 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs762618636, COSV55367450; called by muse, mutect2, varscan2
- CLDN34 | c.140del p.P47Lfs*48 | Frame Shift Del (DEL) | VAF 70/452 reads (15%) | catalogued as rs916875657; called by mutect2, varscan2
- CLIC6 | c.1751C>T p.T584M (on ENST00000360731 / NM_001317009.2; = p.T566M on NM_053277.3) | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs753768078, COSV62447444; called by muse, mutect2, varscan2
- CLOCK | c.2515G>A p.D839N | Missense Mutation (SNP) | VAF 54/347 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV59401496; called by muse, mutect2, varscan2
- CLPTM1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 73/370 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs769057466, COSV61612402; called by muse, mutect2, varscan2
- CMTM2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 31/566 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1386469520, COSV51749747; called by muse, mutect2
- CNTLN | c.3898C>T p.R1300* | Nonsense Mutation (SNP) | VAF 60/304 reads (20%) | catalogued as rs757732796; called by muse, mutect2, varscan2
- COBL | c.2699C>T p.A900V | Missense Mutation (SNP) | VAF 68/462 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs372266870; called by muse, mutect2, varscan2
- COG1 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 96/465 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs552223280, COSV55430557; called by muse, mutect2, varscan2
- COG6 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 63/374 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs764437648, COSV62997167; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.2188G>A p.G730R | Missense Mutation (SNP) | VAF 71/386 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1297620940; called by muse, mutect2, varscan2
- COL6A3 | c.8821G>A p.A2941T | Missense Mutation (SNP) | VAF 80/462 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99800014; called by muse, mutect2, varscan2
- COL7A1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs747699511, COSV100097989, COSV60397222; called by muse, mutect2, varscan2
- CORIN | c.2843G>A p.R948H | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs144827232; called by muse, mutect2, varscan2
- CORO7 | c.1205del p.P402Lfs*13 | Frame Shift Del (DEL) | VAF 44/447 reads (10%) | catalogued as rs1350824419; called by mutect2, pindel, varscan2
- CPSF7 | c.1339C>T p.R447W (on ENST00000394888 / NM_001136040.4; = p.R490W on NM_024811.4) | Missense Mutation (SNP) | VAF 57/394 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV61211952; called by muse, mutect2, varscan2
- CPTP | c.123-1G>T p.X41_splice | Splice Site (SNP) | VAF 16/230 reads (7%) | catalogued as COSV100027845; called by muse, mutect2
- CSMD1 | c.6716G>T p.S2239I (on ENST00000520002; = p.S2238I on NM_033225.6) | Missense Mutation (SNP) | VAF 15/453 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59298768; called by muse, mutect2
- CSNK1G3 | c.145del p.I49Lfs*11 | Frame Shift Del (DEL) | VAF 58/381 reads (15%) | catalogued as rs775129818, COSV62054115, COSV62057434; called by mutect2, varscan2
- CST1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 69/377 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs569786302, COSV59055308; called by muse, mutect2, varscan2
- CSTF2T | c.1018G>T p.G340W | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100484291; called by muse, mutect2, varscan2
- CXCR2 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 79/480 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs764203501, COSV59280046, COSV59281534; called by muse, mutect2, varscan2
- CYP26A1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 16/483 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV56417362; called by muse, mutect2
- CYP4V2 | c.571del p.Y191Tfs*7 | Frame Shift Del (DEL) | VAF 22/159 reads (14%) | catalogued as rs1467050790; called by mutect2, varscan2
- CYYR1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV54832373, COSV54839783; called by muse, mutect2, varscan2
- DBNDD2 | c.562del p.Q188Sfs*12 | Frame Shift Del (DEL) | VAF 77/460 reads (17%) | catalogued as rs1320987043; called by mutect2, pindel, varscan2
- DCHS1 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 52/544 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs946492228, COSV100201660; called by muse, mutect2
- DDX58 | c.1923C>T p.D641= | Splice Region (SNP) | VAF 51/239 reads (21%) | catalogued as rs755898188; called by muse, mutect2, varscan2
- DENND3 | c.3275C>T p.A1092V | Missense Mutation (SNP) | VAF 55/416 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs143494640, COSV52802946; called by muse, mutect2, varscan2
- DFFB | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs368975039; called by muse, mutect2, varscan2
- DHDH | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs762549322; called by muse, varscan2
- DHRSX | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as rs1227565169, COSV58136814; called by muse, mutect2, varscan2
- DIP2C | c.2098A>G p.T700A | Missense Mutation (SNP) | VAF 81/462 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.515); catalogued as COSV99792943; called by muse, mutect2, varscan2
- DLC1 | c.3347C>T p.S1116L (on ENST00000276297 / NM_001348081.2; = p.S679L on NM_006094.5) | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs867572567, COSV52290647; called by muse, mutect2
- DMD | c.6863A>G p.Q2288R | Missense Mutation (SNP) | VAF 33/519 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs762708936; ClinVar: uncertain significance; called by muse, mutect2
- DNAH11 | c.6212A>C p.K2071T | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60965483; called by muse, mutect2, varscan2
- DNAH6 | c.7705C>T p.R2569C | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1428887330; called by muse, mutect2, varscan2
- DNTT | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs1286283190; called by muse, mutect2, varscan2
- DOCK7 | c.4355G>A p.R1452H (on ENST00000635253 / NM_001367561.1; = p.R1421H on NM_033407.3) | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1381692784; called by muse, mutect2, varscan2
- DOT1L | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs752264656, COSV67110438; called by muse, mutect2, varscan2
- DPP6 | c.978G>A p.M326I (on ENST00000377770 / NM_001364500.2; = p.M264I on NM_001936.5) | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100124391; called by muse, varscan2
- DRP2 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 97/487 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65811079; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 36/228 reads (16%) | catalogued as rs755197346; called by mutect2, varscan2
- DYSF | c.3752G>A p.R1251Q | Missense Mutation (SNP) | VAF 92/484 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as rs759192836; called by muse, mutect2, varscan2
- DZIP1 | c.1685T>C p.I562T (on ENST00000347108; = p.I543T on NM_014934.5) | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV61264277; called by muse, mutect2
- E2F7 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59743756; called by muse, mutect2, varscan2
- EDEM1 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 79/393 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56581774; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2551C>T p.R851C | Missense Mutation (SNP) | VAF 86/488 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373409868; called by muse, mutect2, varscan2
- EEF1B2 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs1016954212; called by muse, mutect2, varscan2
- EGFR | c.2170G>A p.G724S | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1051753269, COSV51788393; ClinVar: not provided; called by muse, mutect2, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 46/208 reads (22%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF4G1 | c.3530C>T p.A1177V (on ENST00000346169 / NM_198241.3; = p.A982V on NM_004953.5) | Missense Mutation (SNP) | VAF 83/444 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs773375468, COSV59990652; called by muse, mutect2, varscan2
- ELAPOR1 | c.1640C>T p.T547M | Missense Mutation (SNP) | VAF 60/357 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs762679826; called by muse, mutect2, varscan2
- ELAVL3 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 60/384 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs757854568, COSV52954062; called by muse, varscan2
- ELF3 | c.478+1_478+3del p.X160_splice | Splice Site (DEL) | VAF 49/239 reads (21%) | catalogued as rs995289305; called by mutect2, pindel, varscan2
- ELMOD2 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.829); catalogued as rs375756274; called by muse, mutect2, varscan2
- EN1 | c.171del p.S58Rfs*54 | Frame Shift Del (DEL) | VAF 34/245 reads (14%) | catalogued as rs1363146947; called by mutect2, pindel, varscan2
- EPB41L5 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770943181, COSV55353134; called by muse, varscan2
- ERAP1 | c.2836G>A p.A946T | Missense Mutation (SNP) | VAF 32/315 reads (10%) | PolyPhen benign (0); catalogued as rs372808514; called by muse, mutect2, varscan2
- ERBB4 | c.3763C>G p.H1255D | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV61481849; called by muse, mutect2, varscan2
- ERI3 | c.39del p.R14Gfs*55 | Frame Shift Del (DEL) | VAF 63/373 reads (17%) | catalogued as rs1184349425; called by mutect2, pindel, varscan2
- ERICH3 | c.4439G>A p.R1480Q | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1365847080; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 42/232 reads (18%) | catalogued as rs753821453; called by mutect2, varscan2
- ERN2 | c.2320del p.Q774Rfs*35 | Frame Shift Del (DEL) | VAF 76/448 reads (17%) | catalogued as rs1567242682; called by mutect2, pindel, varscan2
- EVX2 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.045); catalogued as rs1287309577; called by muse, varscan2
- EVX2 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 83/474 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV57963550; called by muse, mutect2, varscan2
- FA2H | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 60/308 reads (19%) | catalogued as rs1463651673, COSV54727930; called by muse, mutect2, varscan2
- FAAH2 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs895160462, COSV100887448; called by muse, mutect2, varscan2
- FAAH2 | c.1296A>T p.E432D | Missense Mutation (SNP) | VAF 68/461 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.05); catalogued as COSV66507203; called by muse, mutect2, varscan2
- FAM117A | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs759071955; called by muse, mutect2, varscan2
- FAM189B | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 82/468 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771965794; called by muse, mutect2, varscan2
- FAM222A | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 56/329 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as rs745618000, COSV100734597; called by muse, mutect2, varscan2
- FAM47B | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 61/418 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs781229202, COSV61457625; called by muse, mutect2, varscan2
- FAM47C | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 88/608 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs781997233, COSV63731372; called by muse, mutect2, varscan2
- FAM83H | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 96/673 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782036478, COSV66353626; called by muse, mutect2, varscan2
- FANCD2OS | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 69/427 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs771032579; called by muse, mutect2, varscan2
- FAT3 | c.3588del p.F1196Lfs*9 | Frame Shift Del (DEL) | VAF 35/225 reads (16%) | catalogued as COSV53094622; called by mutect2, pindel, varscan2
- FAT3 | c.9386del p.P3129Lfs*22 | Frame Shift Del (DEL) | VAF 47/313 reads (15%) | catalogued as COSV99962642; called by mutect2, varscan2
- FBRSL1 | c.2739del p.A914Pfs*90 | Frame Shift Del (DEL) | VAF 38/240 reads (16%) | catalogued as rs1566257864; called by pindel, varscan2
- FBXL8 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 68/339 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.521); catalogued as rs1382589204; called by muse, mutect2, varscan2
- FBXO11 | c.1295C>T p.A432V (on ENST00000403359 / NM_001190274.2; = p.A348V on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV57016534; called by muse, mutect2
- FBXO25 | c.199del p.R67Gfs*44 (on ENST00000382824 / NM_183421.2; = p.G17Efs*6 on NM_012173.3) | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | catalogued as rs758426962; called by mutect2, pindel, varscan2
- FBXO31 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 67/422 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs187880966; called by muse, varscan2
- FCHSD2 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 77/426 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs755994711, COSV60810002; called by muse, mutect2, varscan2
- FERMT2 | c.455del p.K152Rfs*4 | Frame Shift Del (DEL) | VAF 48/315 reads (15%) | catalogued as rs766229731; called by mutect2, varscan2
- FLNA | c.5009C>T p.T1670M (on ENST00000369850 / NM_001110556.2; = p.T1662M on NM_001456.3) | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs1381802174; ClinVar: uncertain significance; called by muse, mutect2
- FLNB | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 69/403 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773454165; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1161del p.L388Yfs*25 | Frame Shift Del (DEL) | VAF 40/231 reads (17%) | catalogued as rs1291679708, COSV100437911; called by mutect2, pindel, varscan2
- FRAS1 | c.8954A>G p.D2985G | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs868780494, COSV53610953; called by muse, mutect2
- FREM2 | c.2238del p.T747Qfs*17 | Frame Shift Del (DEL) | VAF 52/358 reads (15%) | catalogued as rs113570727; called by mutect2, varscan2
- FRMD1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 72/462 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs144351021; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 100/576 reads (17%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FSCN3 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs148605578; called by muse, mutect2, varscan2
- FTMT | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 61/439 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58420670, COSV58421858; called by muse, mutect2, varscan2
- FZD2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1208609685; called by muse, mutect2, varscan2
- GIGYF2 | c.2263C>T p.R755* | Nonsense Mutation (SNP) | VAF 56/436 reads (13%) | catalogued as COSV65246625; called by muse, mutect2, varscan2
- GJA8 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 76/343 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587710840, COSV53787626; ClinVar: uncertain significance; called by mutect2, varscan2
- GJB4 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 78/526 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as rs773421859, COSV58357048; called by muse, mutect2, varscan2
- GLCE | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs552257481, COSV55944119; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 76/500 reads (15%) | catalogued as rs759448855, COSV99954330; called by mutect2, varscan2
- GLT8D1 | c.238dup p.A80Gfs*37 | Frame Shift Ins (INS) | VAF 80/460 reads (17%) | catalogued as rs754869681; called by mutect2, varscan2
- GNPDA1 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1054193183, COSV60942726; called by muse, mutect2
- GNRHR | c.941del p.L314* | Frame Shift Del (DEL) | VAF 27/184 reads (15%) | catalogued as CM004721; called by mutect2, pindel, varscan2
- GOLGA4 | c.4098del p.V1367Lfs*10 | Frame Shift Del (DEL) | VAF 44/232 reads (19%) | catalogued as rs768760517; called by mutect2, varscan2
- GOLGB1 | c.8246A>G p.H2749R | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs751905403; called by muse, mutect2, varscan2
- GPR151 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 62/415 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1276954067; called by muse, mutect2, varscan2
- GPR55 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 88/432 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs774169195, COSV67407495; called by muse, varscan2
- GRIN2C | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 40/522 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as rs778467814; called by muse, mutect2
- GRIP2 | c.1124G>A p.R375H (on ENST00000619221; = p.R278H on NM_001080423.4) | Missense Mutation (SNP) | VAF 31/487 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as rs745456325; called by muse, mutect2
- H1-5 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 22/396 reads (6%) | catalogued as rs1411789695, COSV58900014; called by muse, mutect2
- H3Y1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT tolerated, low confidence (0.05); catalogued as rs1456371513; called by muse, mutect2
- HAPLN4 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 64/380 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as rs770259089, COSV52269799; called by muse, mutect2, varscan2
- HARS2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 49/335 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761054820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC6 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 93/534 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs781835578, COSV61930479, COSV61930846; called by muse, mutect2, varscan2
- HDC | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 75/448 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772945540, COSV51069711; called by muse, mutect2, varscan2
- HDLBP | c.2954G>A p.R985H | Missense Mutation (SNP) | VAF 56/396 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs762778846; called by muse, mutect2, varscan2
- HEATR5B | c.5852C>T p.A1951V | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762648818, COSV51861288; called by mutect2, varscan2
- HGF | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768451705, COSV55947351, COSV55955898; called by muse, mutect2, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 49/273 reads (18%) | catalogued as rs199474609; called by mutect2, pindel, varscan2
- HMGCS2 | c.1156C>A p.L386M | Missense Mutation (SNP) | VAF 65/396 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.712); catalogued as rs1378975136; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 18/141 reads (13%) | catalogued as rs761272507; called by mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 47/256 reads (18%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HYAL3 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 80/408 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs142315421; called by muse, mutect2, varscan2
- IFIT3 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 83/428 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs755384820; called by muse, mutect2, varscan2
- IFT122 | c.1989G>T p.K663N (on ENST00000348417 / NM_052989.3; = p.K604N on NM_018262.4) | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV56200079; called by muse, mutect2, varscan2
- IFT46 | c.882A>C p.Q294H (on ENST00000264021 / NM_001168618.2; = p.Q345H on NM_020153.3) | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs562165126; called by muse, mutect2, varscan2
- IGFALS | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 78/405 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763212867; called by muse, mutect2, varscan2
- IGSF10 | c.4928A>G p.Y1643C | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1419183095, COSV56792205; called by muse, mutect2
- INO80C | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs777707802, COSV58046764; called by muse, mutect2, varscan2
- INO80E | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs1400971621; called by muse, mutect2
- IQCJ-SCHIP1 | c.334A>G p.S112G (on ENST00000485419 / NM_001197113.1; = p.S36G on NM_014575.3) | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs763999926, COSV61843595; called by mutect2, varscan2
- IQGAP3 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV100752341, COSV63252757; called by muse, mutect2
- IRX4 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 53/590 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs764889413; called by muse, mutect2
- ITGA10 | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 17/385 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs782806442; called by muse, mutect2
- ITGA6 | c.841C>T p.P281S (on ENST00000442250; = p.P123S on NM_001316306.2) | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99906134; called by muse, mutect2, varscan2
- ITGAX | c.3322del p.L1108Sfs*3 | Frame Shift Del (DEL) | VAF 74/421 reads (18%) | catalogued as rs1430644110, COSV51648913; called by mutect2, pindel, varscan2
- JAKMIP3 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 76/502 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs778567934, COSV53827124; called by muse, mutect2, varscan2
- KCND1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 82/538 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as rs1557058654; called by muse, mutect2, varscan2
- KCNH4 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 110/489 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.165); catalogued as rs1488706304, COSV99237495; called by muse, mutect2, varscan2
- KCNJ2 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 24/486 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM150737, COSV99696226; called by muse, mutect2
- KCNT1 | c.1375G>A p.V459M (on ENST00000488444; = p.V478M on NM_020822.3) | Missense Mutation (SNP) | VAF 49/337 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs766714200, COSV53695874; called by muse, mutect2, varscan2
- KCNV1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 92/570 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1293283795; called by muse, mutect2, varscan2
- KCTD13 | c.421del p.R141Gfs*13 | Frame Shift Del (DEL) | VAF 40/285 reads (14%) | catalogued as rs766440565; called by mutect2, varscan2
- KCTD3 | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 69/435 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs745515630, COSV52066599; called by muse, mutect2, varscan2
- KHSRP | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs369479127; called by muse, mutect2, varscan2
- KIAA1549 | c.3200G>A p.R1067H | Missense Mutation (SNP) | VAF 63/393 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as rs1047219909, COSV54313653; called by muse, mutect2, varscan2
- KIF13A | c.3817C>T p.R1273* | Nonsense Mutation (SNP) | VAF 109/334 reads (33%) | catalogued as rs757826120; called by muse, mutect2, varscan2
- KIF22 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs1184519088; called by muse, mutect2, varscan2
- KIR3DL2 | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 84/522 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs546528999; called by muse, varscan2
- KLC4 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 64/360 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770988742; called by muse, mutect2, varscan2
- KLHL15 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 14/332 reads (4%) | catalogued as COSV60142001; called by muse, mutect2
- KLHL35 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs762036999; called by muse, mutect2, varscan2
- KLK5 | c.741del p.P248Lfs*65 | Frame Shift Del (DEL) | VAF 46/301 reads (15%) | catalogued as rs759781166; called by mutect2, varscan2
- KMT2B | c.3057del p.G1020Afs*4 | Frame Shift Del (DEL) | VAF 65/325 reads (20%) | catalogued as rs868041281; called by mutect2, pindel, varscan2
- KRT20 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 110/606 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV51425051; called by muse, mutect2, varscan2
- KRT28 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 93/487 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1390563780; called by muse, mutect2, varscan2
- KRT74 | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 124/407 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs752005325; called by muse, mutect2, varscan2
- KRTAP4-11 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 109/596 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs571487800, COSV66948033; called by muse, mutect2, varscan2
- KRTAP4-12 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 114/652 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.396); catalogued as rs143774183; called by muse, mutect2, varscan2
- LAMA3 | c.4159C>T p.R1387W | Missense Mutation (SNP) | VAF 65/352 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs746123848, COSV100558062; called by muse, mutect2, varscan2
- LAMB1 | c.3844G>A p.A1282T | Missense Mutation (SNP) | VAF 32/580 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs767881160, COSV55961529; called by muse, mutect2
- LAMP5 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 57/373 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.037); catalogued as rs527594563, COSV55715265; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 34/285 reads (12%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LENG8 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 87/446 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as rs1034777924; called by muse, mutect2, varscan2
- LGALS13 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 64/390 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751763395, COSV55679855, COSV55681051; called by muse, mutect2, varscan2
- LHFPL3 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 62/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67809913; called by muse, varscan2
- LOXHD1 | c.5378A>C p.Q1793P (on ENST00000642948; = p.Q1731P on NM_144612.7) | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV56062337; called by muse, varscan2
- LRP1 | c.9821G>A p.R3274Q | Missense Mutation (SNP) | VAF 80/558 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.213); catalogued as rs773955803, COSV54522692; called by muse, mutect2
- LRRC14B | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 28/504 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs1277387746, COSV57256210; called by muse, mutect2
- LRRC58 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 30/386 reads (8%) | catalogued as rs531487020; called by muse, mutect2
- MAN1C1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 107/553 reads (19%) | catalogued as COSV56049559; called by muse, mutect2, varscan2
- MAPK8IP1 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 76/468 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs775633425, COSV99571327; called by muse, mutect2, varscan2
- MARK4 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1181776226, COSV53465677; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 21/114 reads (18%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM3AP | c.3773G>A p.R1258H | Missense Mutation (SNP) | VAF 59/354 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as rs372593235; called by mutect2, varscan2
- MCM3AP | c.3595A>G p.T1199A | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1248252077; called by muse, mutect2, varscan2
- MED12L | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 74/517 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1161292258, COSV56368619; called by muse, mutect2, varscan2
- MEIS2 | c.167del p.P56Rfs*18 (on ENST00000561208 / NM_170675.5; = p.P43Rfs*18 on NM_002399.3) | Frame Shift Del (DEL) | VAF 93/555 reads (17%) | catalogued as COSV54943726, COSV99576080; called by mutect2, pindel, varscan2
- MGA | c.7273C>T p.R2425C (on ENST00000219905 / NM_001164273.1; = p.R2216C on NM_001080541.2) | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54948460; called by muse, mutect2, varscan2
- MICAL3 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1255841609, COSV52895446; called by muse, mutect2
- MICU3 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58848433, COSV58849526; called by muse, mutect2, varscan2
- MKRN3 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 26/493 reads (5%) | catalogued as rs1395164226, COSV58808600, COSV58811332; called by muse, mutect2
- MMP2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 68/405 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs753129923; called by muse, mutect2, varscan2
- MON2 | c.1214del p.P405Lfs*16 | Frame Shift Del (DEL) | VAF 73/284 reads (26%) | catalogued as rs774904019; called by mutect2, pindel, varscan2
- MORC3 | c.1726G>C p.D576H | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68687879; called by muse, mutect2, varscan2
- MRGPRE | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 84/468 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs756116749; called by muse, mutect2, varscan2
- MRPL52 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs750625277; called by muse, mutect2, varscan2
- MSANTD1 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1467505461; called by muse, mutect2, varscan2
- MUC5B | c.14591C>T p.T4864M | Missense Mutation (SNP) | VAF 94/553 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.202); catalogued as rs751209696; called by muse, mutect2, varscan2
- MYH10 | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 77/441 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs777490499, COSV104369030; called by muse, mutect2, varscan2
- MYO3B | c.3671G>A p.R1224Q | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs750028664, COSV100508841, COSV58707708; called by muse, mutect2, varscan2
- MYO6 | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs755596824; called by muse, mutect2, varscan2
- MYPN | c.2437T>C p.S813P | Missense Mutation (SNP) | VAF 64/372 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1288555598; called by mutect2, varscan2
- NEB | c.17867C>T p.T5956M | Missense Mutation (SNP) | VAF 50/357 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770889470, COSV99413890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 83/413 reads (20%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NEXN | c.1399del p.I467* | Frame Shift Del (DEL) | VAF 21/204 reads (10%) | catalogued as rs1365488625; called by mutect2, pindel, varscan2
- NF1 | c.3268G>T p.G1090* | Nonsense Mutation (SNP) | VAF 29/174 reads (17%) | catalogued as CM143370, COSV62200142, COSV62210918; called by mutect2, varscan2
- NFATC1 | c.2782G>A p.V928I (on ENST00000427363 / NM_001278669.2; = p.V915I on NM_172387.3) | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs780754685, COSV53705594; called by muse, mutect2, varscan2
- NKD2 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 76/533 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.329); catalogued as rs145184317; called by muse, mutect2, varscan2
- NKX6-1 | c.144del p.S49Pfs*24 | Frame Shift Del (DEL) | VAF 79/344 reads (23%) | catalogued as rs746875959; called by mutect2, varscan2
- NLGN4X | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 75/465 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as rs1336724790, COSV52037556; called by muse, mutect2, varscan2
- NLRP1 | c.3962C>T p.S1321L (on ENST00000572272 / NM_033004.4; = p.S1277L on NM_014922.5) | Missense Mutation (SNP) | VAF 57/397 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289681813, COSV52559527; called by muse, mutect2, varscan2
- NLRP2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 74/492 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs373538812; called by muse, mutect2, varscan2
- NLRP2 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 86/417 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.951); catalogued as rs1473452983, COSV54751859, COSV54752546; called by muse, mutect2, varscan2
- NLRP7 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 91/520 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765446538, COSV100052239, COSV60170834; called by muse, mutect2, varscan2
- NMB | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1297279401; called by muse, mutect2
- NOD2 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 73/421 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.014); catalogued as COSV56050581; called by muse, mutect2, varscan2
- NOS1 | c.387del p.T130Pfs*80 | Frame Shift Del (DEL) | VAF 66/488 reads (14%) | catalogued as COSV100500300; called by mutect2, varscan2
- NOS3 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 73/409 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374834315; called by muse, mutect2
- NPPB | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs777621972, COSV64687232; called by muse, mutect2, varscan2
- NRCAM | c.2924C>T p.P975L (on ENST00000379028 / NM_001371124.1; = p.P959L on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1038783254, COSV61039896; called by muse, mutect2, varscan2
- NRG1 | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99830067; called by muse, mutect2
- NRXN1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 87/485 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs202242910; called by muse, mutect2, varscan2
- NSD1 | c.5296C>T p.R1766* | Nonsense Mutation (SNP) | VAF 8/179 reads (4%) | catalogued as CM052311, COSV100728748; called by muse, mutect2
- NUDT1 | c.310A>G p.M104V (on ENST00000397048 / NM_198952.1; = p.M81V on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/433 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs750814893; called by muse, mutect2, varscan2
- NUP210 | c.403del p.L135Wfs*3 | Frame Shift Del (DEL) | VAF 55/343 reads (16%) | catalogued as rs762804106; called by mutect2, pindel, varscan2
- OPCML | c.455G>C p.S152T | Missense Mutation (SNP) | VAF 69/351 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1215143100; called by muse, mutect2, varscan2
- OPLAH | c.3221C>T p.A1074V | Missense Mutation (SNP) | VAF 91/528 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1554757941, COSV70677818; called by muse, mutect2, varscan2
- OR10Q1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 45/377 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs756706102, COSV100372412; called by muse, mutect2, varscan2
- OR10W1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs749730574, COSV101223792, COSV67720689; called by muse, mutect2, varscan2
- OR11L1 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 63/399 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs775013258; called by muse, mutect2, varscan2
- OR2T8 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 53/297 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.187); catalogued as rs761784379, COSV60661821, COSV60662119; called by muse, mutect2, varscan2
- OR4C6 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 63/419 reads (15%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs759192087; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 56/360 reads (16%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52E5 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 87/397 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV68538282; called by muse, mutect2, varscan2
- OR7E24 | c.504del p.F168Lfs*12 | Frame Shift Del (DEL) | VAF 65/360 reads (18%) | catalogued as rs1031417078; called by mutect2, varscan2
- P2RX7 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.933); catalogued as COSV55855098; called by muse, mutect2
- PADI2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 70/457 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs367699636, COSV64945455; called by muse, mutect2, varscan2
- PADI6 | c.441dup p.W148Mfs*20 | Frame Shift Ins (INS) | VAF 36/231 reads (16%) | catalogued as rs1275178104; called by mutect2, pindel, varscan2
- PARP14 | c.487A>G p.I163V | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1466590876; called by muse, mutect2, varscan2
- PCDH17 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 24/449 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64975852; called by muse, mutect2
- PCDH17 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 67/441 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64978045; called by muse, mutect2, varscan2
- PCDHA11 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 31/421 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as rs543880939, COSV56529710; called by muse, mutect2
- PCDHB10 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 68/422 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.021); catalogued as COSV53375036; called by muse, mutect2, varscan2
- PCDHB4 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 121/863 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52025265; called by muse, mutect2, varscan2
- PCDHGA3 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 101/628 reads (16%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV53904010; called by muse, mutect2, varscan2
- PCDHGA6 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 75/496 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1194415432, COSV53906621; called by muse, mutect2, varscan2
- PCDHGA6 | c.2078T>C p.L693P | Missense Mutation (SNP) | VAF 116/704 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53905070; called by muse, mutect2, varscan2
- PCDHGA9 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 67/504 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.298); catalogued as COSV53917968; called by muse, mutect2, varscan2
- PCDHGB7 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 70/483 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.378); catalogued as rs755798236, COSV99548670; called by muse, varscan2
- PCLO | c.4102G>T p.D1368Y | Missense Mutation (SNP) | VAF 69/459 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV61638785, COSV61659459; called by muse, mutect2, varscan2
- PCMTD1 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as rs767756923, COSV62119286; called by muse, mutect2
- PDE4DIP | c.5605C>T p.R1869W | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs370147814; called by muse, mutect2, varscan2
- PDGFB | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs773106218, COSV58645562; called by muse, mutect2, varscan2
- PDIA3 | c.327del p.E110Kfs*19 | Frame Shift Del (DEL) | VAF 39/267 reads (15%) | catalogued as COSV55858152; called by mutect2, pindel, varscan2
- PDIA4 | c.1432G>A p.A478T (on ENST00000286091 / NM_001371244.1; = p.A477T on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/376 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs774716231, COSV99618424; called by muse, mutect2, varscan2
- PDZRN4 | c.2410G>A p.A804T (on ENST00000402685 / NM_001164595.2; = p.A546T on NM_013377.4) | Missense Mutation (SNP) | VAF 47/368 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs375067300; called by muse, mutect2, varscan2
- PEAK1 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 53/320 reads (17%) | catalogued as COSV100433526; called by muse, mutect2, varscan2
- PEX14 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 109/512 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.089); catalogued as rs776350064; called by muse, mutect2, varscan2
- PGAP6 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 58/317 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.077); catalogued as rs367909295; called by muse, mutect2, varscan2
- PGLYRP2 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 89/459 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV52993349; called by muse, mutect2, varscan2
- PHF21A | c.1075C>T p.R359W (on ENST00000418153 / NM_001101802.3; = p.R360W on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/331 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs779958949, COSV57657762; called by muse, mutect2, varscan2
- PIEZO1 | c.4630C>T p.R1544W | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs976006615; called by muse, varscan2
- PIGT | c.1043del p.P348Qfs*11 | Frame Shift Del (DEL) | VAF 49/309 reads (16%) | catalogued as rs749895437; called by mutect2, pindel, varscan2
- PIK3C2B | c.4684C>T p.R1562W | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs371494234, COSV100916234; called by muse, mutect2, varscan2
- PIK3C2B | c.3931A>G p.N1311D | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1184088462; called by muse, mutect2, varscan2
- PIK3CA | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 51/292 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1401795892; called by muse, mutect2, varscan2
- PITPNM3 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 101/436 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387762572, COSV52600078; called by muse, mutect2, varscan2
- PKD1L1 | c.1672del p.R558Dfs*10 | Frame Shift Del (DEL) | VAF 58/362 reads (16%) | catalogued as rs897900295; called by mutect2, pindel, varscan2
- PKN1 | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 21/520 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1395499644; called by muse, mutect2
- PLA2G4F | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 38/464 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.285); catalogued as rs748808087; called by muse, mutect2
- PLCH1 | c.3221G>A p.C1074Y (on ENST00000340059 / NM_001130960.2; = p.C1066Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/442 reads (14%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.021); catalogued as rs1220558983, COSV58205703; called by muse, mutect2, varscan2
- PLEKHG2 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs867114386; called by muse, mutect2, varscan2
- PLIN1 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 91/450 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs530426616; called by muse, mutect2, varscan2
- PLXNB2 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 78/449 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.195); catalogued as rs764196872; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 72/401 reads (18%) | catalogued as rs745933237; called by mutect2, varscan2
- POR | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 82/527 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs1554559125; called by muse, mutect2, varscan2
- POTEI | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs775721804; called by mutect2, varscan2
- PPP1R7 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV99298190; called by muse, mutect2, varscan2
- PRAG1 | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 86/506 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV58162237; called by muse, varscan2
- PRICKLE4 | c.953G>A p.R318H (on ENST00000359201; = p.R358H on NM_013397.6) | Missense Mutation (SNP) | VAF 55/331 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV100138917; called by muse, mutect2, varscan2
- PRRT2 | c.25T>A p.S9T | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.269); catalogued as rs749879243; called by mutect2, varscan2
- PRSS57 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 56/394 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.041); catalogued as rs760617017; called by muse, mutect2, varscan2
- PSD | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as COSV50063554; called by muse, mutect2, varscan2
- PSMD9 | c.436T>C p.S146P | Missense Mutation (SNP) | VAF 39/357 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1304198276; called by muse, mutect2, varscan2
- PTCH1 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 68/363 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV59466751; called by muse, mutect2, varscan2
- PTH1R | c.548T>C p.V183A | Missense Mutation (SNP) | VAF 23/388 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs1216360583; called by muse, mutect2
- PTPRA | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773634271, COSV53780312; called by muse, mutect2, varscan2
- PUM1 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 84/462 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs772493608, COSV57088812; called by muse, mutect2, varscan2
- PWP1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 97/581 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs748712055, COSV69832449; called by muse, mutect2, varscan2
- QRFPR | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 38/526 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.689); catalogued as rs939125688, COSV57676932; called by muse, mutect2
- RANBP2 | c.6115C>T p.R2039W | Missense Mutation (SNP) | VAF 40/557 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766455181; called by muse, mutect2
- RASA1 | c.2513del p.N838Mfs*4 | Frame Shift Del (DEL) | VAF 14/101 reads (14%) | catalogued as rs1561325048; called by mutect2, pindel, varscan2
- RBM25 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 108/519 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as rs1430524307; called by muse, mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 39/272 reads (14%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBMXL3 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 84/546 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.484); catalogued as rs1370796673; called by muse, mutect2, varscan2
- RCCD1 | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs757241432, COSV101263253; called by muse, varscan2
- RFTN1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 94/469 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs368097786, COSV100489878; called by muse, mutect2, varscan2
- RFX1 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 50/349 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs753088781, COSV54332692; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 36/168 reads (21%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RHBDF2 | c.1857G>A p.M619I | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV51686135; called by muse, mutect2, varscan2
- RIBC1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 21/629 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as rs368172317; called by muse, mutect2
- RIMS3 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as rs557060980, COSV65504611; called by muse, mutect2, varscan2
- RNASEH2B | c.509del p.K170Rfs*9 | Frame Shift Del (DEL) | VAF 17/111 reads (15%) | catalogued as rs1085307091, COSV60747894; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- RND3 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.023); catalogued as rs772557837; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 36/193 reads (19%) | catalogued as rs757038390; called by mutect2, varscan2
- RPF1 | c.952T>C p.S318P | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs759783846; called by muse, mutect2, varscan2
- RPN1 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 50/313 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs200124017; called by muse, mutect2, varscan2
- RSPH4A | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 37/540 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); catalogued as rs761222226; called by muse, mutect2
- RUBCN | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 81/422 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747642944, COSV56365934; called by muse, mutect2, varscan2
- RUSC2 | c.1817T>C p.M606T | Missense Mutation (SNP) | VAF 86/492 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs760524309; called by muse, mutect2, varscan2
- RYR1 | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 18/528 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs933347966, COSV100614977; called by muse, mutect2
- SBNO2 | c.1885C>T p.R629W | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1487188295; called by muse, mutect2, varscan2
- SCUBE1 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 75/458 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.107); catalogued as rs552279204, COSV51811621; called by muse, mutect2, varscan2
- SCUBE2 | c.2594C>T p.T865M (on ENST00000649792 / NM_001367977.2; = p.T808M on NM_020974.3) | Missense Mutation (SNP) | VAF 94/434 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150620969; called by muse, mutect2, varscan2
- SCX | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 54/346 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1165241192; called by muse, mutect2, varscan2
- SEC14L6 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 68/397 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755389496; called by muse, mutect2, varscan2
- SECISBP2L | c.2108G>A p.R703H (on ENST00000559471 / NM_001193489.2; = p.R658H on NM_014701.4) | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs377231829, COSV55939478; called by muse, mutect2
- SERPINE3 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs367969906; called by muse, mutect2, varscan2
- SEZ6L | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 75/421 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as rs144740621; called by muse, mutect2, varscan2
- SGSM1 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 57/282 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1005956938, COSV68511293; called by muse, mutect2, varscan2
- SGSM3 | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 71/457 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs757913891; called by muse, varscan2
- SIPA1L2 | c.4594C>T p.R1532W | Missense Mutation (SNP) | VAF 91/463 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs369364776; called by muse, mutect2, varscan2
- SLC10A7 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 49/304 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs201501147, COSV53881887; called by muse, mutect2, varscan2
- SLC25A52 | c.610C>T p.R204* (on ENST00000672005; = p.R194* on NM_001034172.4) | Nonsense Mutation (SNP) | VAF 57/454 reads (13%) | catalogued as rs773220569; called by muse, mutect2, varscan2
- SLC4A2 | c.3683G>A p.R1228Q | Missense Mutation (SNP) | VAF 49/401 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs765331375, COSV99879538; called by muse, mutect2, varscan2
- SLC4A5 | c.3236del p.K1079Rfs*29 | Frame Shift Del (DEL) | VAF 79/434 reads (18%) | catalogued as rs778293501; called by mutect2, pindel, varscan2
- SLC66A3 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 62/349 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs140598852; called by muse, mutect2, varscan2
- SLC9A7 | c.923C>A p.A308E | Missense Mutation (SNP) | VAF 66/405 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV60379286; called by muse, mutect2, varscan2
- SLITRK1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 75/410 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV65677758; called by muse, mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 33/156 reads (21%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SNAPC2 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs2303698, COSV55605355; called by muse, mutect2, varscan2
- SOBP | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 71/372 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs756274178; called by muse, mutect2, varscan2
- SOGA1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200552397; called by muse, mutect2, varscan2
- SON | c.5906G>A p.R1969H | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as rs555969166; called by muse, mutect2, varscan2
- SPDYE16 | c.660G>C p.E220D | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1233569359; called by muse, mutect2, varscan2
- SPEF2 | c.5108G>A p.R1703K | Missense Mutation (SNP) | VAF 40/348 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.176); catalogued as rs771434394; called by muse, mutect2, varscan2
- SPEM1 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 75/455 reads (16%) | catalogued as rs368534326; called by muse, mutect2, varscan2
- SRPX2 | c.546dup p.K183Qfs*9 | Frame Shift Ins (INS) | VAF 55/349 reads (16%) | catalogued as rs1443386831; called by mutect2, pindel, varscan2
- ST6GAL2 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 80/482 reads (17%) | PolyPhen benign (0.251); catalogued as rs746401401, COSV64526208; called by muse, mutect2, varscan2
- STK10 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as rs1169068980; called by muse, mutect2
- STXBP6 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773781064, COSV60599520; called by muse, mutect2
- SUSD2 | c.658del p.L220Wfs*58 | Frame Shift Del (DEL) | VAF 61/428 reads (14%) | catalogued as COSV64205492; called by mutect2, pindel, varscan2
- SYT1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 100/358 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs750035344, COSV54038994; called by muse, mutect2, varscan2
- TAB3 | c.430del p.E144Nfs*24 | Frame Shift Del (DEL) | VAF 66/411 reads (16%) | catalogued as COSV55835344, COSV99915893; called by mutect2, pindel, varscan2
- TAGAP | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 71/347 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs777270446, COSV57850378; called by muse, mutect2, varscan2
- TBC1D2 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 50/362 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368931607; called by muse, mutect2, varscan2
- TCF25 | c.729del p.G244Afs*66 | Frame Shift Del (DEL) | VAF 49/286 reads (17%) | catalogued as rs750914338; called by mutect2, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 67/421 reads (16%) | catalogued as COSV61906772; called by mutect2, pindel, varscan2
- TCHH | c.5660G>A p.R1887H | Missense Mutation (SNP) | VAF 85/412 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as rs201952511, COSV64278390; called by muse, mutect2, varscan2
- TDRD15 | c.1899dup p.D634Rfs*2 | Frame Shift Ins (INS) | VAF 26/150 reads (17%) | catalogued as rs1380097647; called by mutect2, varscan2
- TECTA | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs746339702; called by muse, mutect2, varscan2
- TENM4 | c.3872C>T p.A1291V | Missense Mutation (SNP) | VAF 70/381 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV53638812; called by muse, mutect2, varscan2
- TEP1 | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 61/357 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs140773101; called by muse, mutect2, varscan2
- TEX50 | c.323del p.K108Sfs*2 | Frame Shift Del (DEL) | VAF 25/131 reads (19%) | catalogued as rs1355068391; called by mutect2, pindel, varscan2
- THAP8 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 92/484 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1401926088, COSV53077638; called by muse, mutect2, varscan2
- THBD | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 99/483 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.703); catalogued as rs746618505; called by muse, mutect2, varscan2
- TMA16 | c.45del p.V16Sfs*25 | Frame Shift Del (DEL) | VAF 36/214 reads (17%) | catalogued as rs570113265, COSV62187391; called by mutect2, varscan2
- TMBIM1 | c.735C>T p.Y245= | Splice Region (SNP) | VAF 51/300 reads (17%) | catalogued as rs746214426, COSV50311113; called by muse, mutect2, varscan2
- TMC8 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 79/377 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs772823217; called by muse, varscan2
- TMEM132D | c.1543del p.L515Wfs*3 | Frame Shift Del (DEL) | VAF 176/740 reads (24%) | catalogued as rs752992861, COSV101242814; called by mutect2, pindel, varscan2
- TMOD3 | c.282del p.I97Yfs*23 | Frame Shift Del (DEL) | VAF 28/186 reads (15%) | catalogued as rs759399045; called by mutect2, varscan2
- TMTC3 | c.2098G>A p.D700N | Missense Mutation (SNP) | VAF 62/416 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs1332461696; called by muse, mutect2, varscan2
- TNPO3 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 74/464 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs778504249; called by muse, mutect2, varscan2
- TNRC6C | c.3946del p.L1316Wfs*15 | Frame Shift Del (DEL) | VAF 48/280 reads (17%) | catalogued as rs1316060576; called by mutect2, varscan2
- TPSG1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 98/539 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs555418102; called by muse, mutect2, varscan2
- TRAPPC12 | c.1423A>G p.M475V | Missense Mutation (SNP) | VAF 47/343 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1036226494; called by muse, mutect2, varscan2
- TRH | c.319del p.A107Lfs*23 | Frame Shift Del (DEL) | VAF 86/416 reads (21%) | catalogued as rs770451471, COSV57014685; called by mutect2, varscan2
- TRIM11 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 71/441 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.274); catalogued as rs779404237; called by muse, mutect2, varscan2
- TRPC5 | c.2147T>A p.V716D | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99462684; called by muse, mutect2
- TSPYL5 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 104/537 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV59072106; called by muse, mutect2, varscan2
- TTBK1 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 104/454 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs370022725, COSV52488871, COSV52492583; called by muse, mutect2, varscan2
- TTC21A | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.17); catalogued as rs1248539444, COSV99827066; called by muse, mutect2
- TTLL7 | c.2242G>A p.V748I | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1261873728; called by muse, mutect2, varscan2
- TTYH2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 76/388 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs202079153; called by muse, mutect2, varscan2
- TULP3 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.388); catalogued as rs115288066; called by muse, mutect2, varscan2
- UAP1L1 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 83/428 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1204034960, COSV64306451; called by muse, mutect2, varscan2
- ULK1 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 63/422 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs757096105, COSV58859876; called by muse, mutect2, varscan2
- UNC45B | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as rs543327883, COSV52092506; called by muse, mutect2
- UPK3B | c.787G>A p.G263R (on ENST00000257632; = p.P234= on NM_001347684.2) | Missense Mutation (SNP) | VAF 61/457 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs774585357; called by muse, mutect2, varscan2
- USP22 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 51/299 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54945419; called by muse, mutect2, varscan2
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 64/316 reads (20%) | catalogued as rs749830910; called by mutect2, varscan2
- USP31 | c.3691T>C p.S1231P | Missense Mutation (SNP) | VAF 26/472 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV54850508; called by muse, mutect2
- USP34 | c.8800C>T p.R2934C | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs377417702, COSV68405920; called by muse, mutect2, varscan2
- VPS37D | c.748del p.H250Tfs*75 | Frame Shift Del (DEL) | VAF 28/114 reads (25%) | catalogued as rs1563540888; called by mutect2, pindel, varscan2
- WDR31 | c.1006G>A p.A336T (on ENST00000374193 / NM_001006615.3; = p.A335T on NM_145241.5) | Missense Mutation (SNP) | VAF 71/447 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs549756901, COSV59146562; called by muse, mutect2, varscan2
- WSCD1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 23/524 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1029857490, COSV58494323; called by muse, mutect2
- XKR6 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 74/494 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1563217434; called by mutect2, varscan2
- XPO5 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 83/422 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs776910300; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 48/398 reads (12%) | catalogued as rs762052135; called by mutect2, varscan2
- ZBED5 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 29/342 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as rs888073249; called by muse, mutect2
- ZBTB47 | c.1406G>A p.G469D | Missense Mutation (SNP) | VAF 71/420 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1297991911; called by muse, mutect2, varscan2
- ZC3H3 | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 84/672 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs377352455; called by muse, mutect2, varscan2
- ZC4H2 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 19/505 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.221); catalogued as COSV100565194; called by muse, mutect2
- ZFX | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 70/473 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs758942664; called by muse, mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 34/210 reads (16%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF185 | c.2026C>T p.R676C | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs782048779; called by muse, mutect2, varscan2
- ZNF226 | c.2400del p.K800Nfs*3 | Frame Shift Del (DEL) | VAF 20/144 reads (14%) | catalogued as rs201600907; called by mutect2, varscan2
- ZNF365 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 48/365 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1374378888, COSV101237969, COSV67925700; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 39/361 reads (11%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF524 | c.214del p.V72* | Frame Shift Del (DEL) | VAF 73/430 reads (17%) | catalogued as rs1249713061; called by mutect2, pindel, varscan2
- ZNF580 | c.72del p.K25Rfs*166 | Frame Shift Del (DEL) | VAF 60/345 reads (17%) | catalogued as rs777848292; called by mutect2, pindel, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 72/329 reads (22%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF614 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 79/483 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1271607297, COSV54545166; called by muse, mutect2, varscan2
- ZNF618 | c.1844A>G p.Y615C (on ENST00000374126 / NM_001318042.2; = p.Y522C on NM_133374.2) | Missense Mutation (SNP) | VAF 25/462 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55929021; called by muse, mutect2
- ZNF628 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 86/476 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1323810548; called by muse, mutect2, varscan2
- ZNF704 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 72/547 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs1296393001; called by muse, mutect2, varscan2
- ZNF730 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1347520373; called by muse, mutect2, varscan2
- ZNF827 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 29/411 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs780004872, COSV65226939; called by muse, mutect2
- ZXDB | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 110/578 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs764480463; called by muse, varscan2
- ZZEF1 | c.5433A>G p.L1811= | Splice Region (SNP) | VAF 53/284 reads (19%) | catalogued as rs754608676; called by muse, mutect2, varscan2
- A2M | c.1221C>A p.F407L | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); called by muse, mutect2
- ABCA12 | c.1726T>C p.S576P (on ENST00000272895 / NM_173076.3; = p.S258P on NM_015657.3) | Missense Mutation (SNP) | VAF 19/355 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2
- ABCA4 | c.6160A>C p.S2054R | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.442); called by muse, varscan2
- ABCC1 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC4 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ABCC5 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 78/376 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); called by muse, varscan2
- ABCC8 | c.1924-3del | Splice Region (DEL) | VAF 97/526 reads (18%) | called by mutect2, pindel, varscan2
- ABHD17C | c.754T>G p.F252V | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ACAP3 | c.344T>G p.V115G | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ACHE | c.1210C>A p.L404M | Missense Mutation (SNP) | VAF 79/546 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ACKR1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 70/535 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- ADAMTS1 | c.739A>C p.S247R | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADAMTS12 | c.2759C>A p.A920D | Missense Mutation (SNP) | VAF 73/399 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ADAMTS4 | c.2368A>G p.N790D | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.012); called by muse, mutect2
- ADARB1 | c.217del p.T73Hfs*11 | Frame Shift Del (DEL) | VAF 61/375 reads (16%) | called by mutect2, pindel, varscan2
- ADCY8 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 76/412 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADCY8 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 24/598 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2
- ADRA2C | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 17/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AFG3L2 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGBL5 | c.2089+3A>G | Splice Region (SNP) | VAF 65/375 reads (17%) | called by muse, mutect2, varscan2
- AGFG2 | c.209G>A p.C70Y | Missense Mutation (SNP) | VAF 49/291 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH1L1 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ALG9 | c.1196A>G p.Q399R (on ENST00000614444 / NM_001352418.1; = p.Q406R on NM_024740.2) | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALOX12B | c.1968G>T p.E656D | Missense Mutation (SNP) | VAF 64/461 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ALOXE3 | c.1535G>A p.G512D | Missense Mutation (SNP) | VAF 70/348 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMOT | c.954del p.S319Pfs*56 | Frame Shift Del (DEL) | VAF 84/506 reads (17%) | called by mutect2, varscan2
- AMPD2 | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 47/487 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); called by muse, mutect2
- ANKEF1 | c.198T>G p.F66L | Missense Mutation (SNP) | VAF 82/449 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANXA8L1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); called by muse, varscan2
- AP1G2 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 48/386 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ARC | c.528del p.P178Qfs*44 | Frame Shift Del (DEL) | VAF 72/625 reads (12%) | called by mutect2, pindel, varscan2
- ARHGAP22 | c.1677G>T p.E559D | Missense Mutation (SNP) | VAF 47/517 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- ARMC9 | c.1333A>G p.R445G | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASAP1 | c.961A>G p.K321E | Missense Mutation (SNP) | VAF 53/350 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ASB18 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 27/336 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- ASXL1 | c.15_16del p.K6Efs*67 | Frame Shift Del (DEL) | VAF 28/198 reads (14%) | called by mutect2, pindel, varscan2
- ATAD5 | c.3224dup p.L1076Vfs*3 | Frame Shift Ins (INS) | VAF 23/124 reads (19%) | called by mutect2, pindel, varscan2
- ATP11C | c.3146C>A p.P1049H | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP2B3 | c.3495C>A p.D1165E | Missense Mutation (SNP) | VAF 114/596 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP6V1E2 | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- B4GALT3 | c.634del p.R212Gfs*10 | Frame Shift Del (DEL) | VAF 56/459 reads (12%) | called by mutect2, pindel, varscan2
- BCL11A | c.976del p.L326Sfs*61 (on ENST00000335712 / NM_001365609.1; = p.L360Sfs*61 on NM_018014.4) | Frame Shift Del (DEL) | VAF 36/242 reads (15%) | called by mutect2, varscan2
- BCOR | c.3728C>A p.P1243H (on ENST00000378444 / NM_001123385.2; = p.P1209H on NM_017745.6) | Missense Mutation (SNP) | VAF 28/562 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2
- BDP1 | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 63/390 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- BIN3 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2
- BIRC3 | c.583dup p.Y195Lfs*26 | Frame Shift Ins (INS) | VAF 89/468 reads (19%) | called by mutect2, pindel, varscan2
- BOC | c.2207del p.I736Tfs*69 | Frame Shift Del (DEL) | VAF 22/188 reads (12%) | called by mutect2, pindel, varscan2
- BOLL | c.285del p.K95Nfs*9 | Frame Shift Del (DEL) | VAF 19/117 reads (16%) | called by mutect2, pindel, varscan2
- BPIFB3 | c.1321A>G p.N441D | Missense Mutation (SNP) | VAF 76/342 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BRAT1 | c.1705A>C p.M569L | Missense Mutation (SNP) | VAF 55/353 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0); called by mutect2, varscan2
- BRINP2 | c.1682C>A p.P561H | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- C11orf87 | c.342del p.L115Cfs*162 | Frame Shift Del (DEL) | VAF 47/399 reads (12%) | called by mutect2, pindel, varscan2
- C2CD4B | c.462del p.A155Rfs*30 | Frame Shift Del (DEL) | VAF 21/167 reads (13%) | called by mutect2, varscan2
- C8orf58 | c.1093G>T p.G365C (on ENST00000289989 / NM_001013842.3; = p.G357C on NM_173686.3) | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1B | c.4778T>C p.V1593A | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- CAMSAP3 | c.2698G>A p.A900T | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- CASD1 | c.991del p.Y331Tfs*2 | Frame Shift Del (DEL) | VAF 49/380 reads (13%) | called by mutect2, pindel, varscan2
- CCDC102B | c.108del p.R37Gfs*89 | Frame Shift Del (DEL) | VAF 51/298 reads (17%) | called by mutect2, varscan2
- CCDC97 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC9B | c.478del p.E160Sfs*7 | Frame Shift Del (DEL) | VAF 62/362 reads (17%) | called by mutect2, pindel, varscan2
- CCN3 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 32/469 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCR10 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 34/432 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2
- CD300LF | c.43+1G>C p.X15_splice | Splice Site (SNP) | VAF 48/351 reads (14%) | called by muse, mutect2, varscan2
- CD69 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 19/323 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2
- CDHR1 | c.1721del p.P574Lfs*14 | Frame Shift Del (DEL) | VAF 58/354 reads (16%) | called by mutect2, pindel, varscan2
- CDKAL1 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 27/173 reads (16%) | called by muse, mutect2, varscan2
- CDS2 | c.344A>T p.N115I | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- CEACAM20 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 74/474 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CELF4 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 20/350 reads (6%) | called by muse, mutect2
- CELSR2 | c.5189T>C p.L1730P | Missense Mutation (SNP) | VAF 77/481 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CENPF | c.3700C>A p.L1234M | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2
- CEP192 | c.6316G>T p.G2106C | Missense Mutation (SNP) | VAF 54/379 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CEP250 | c.5900A>G p.Q1967R | Missense Mutation (SNP) | VAF 84/467 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CFAP298 | c.725T>G p.L242R | Missense Mutation (SNP) | VAF 71/349 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CFAP69 | c.484T>C p.C162R | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- CHD9 | c.2108dup p.E704Gfs*9 | Frame Shift Ins (INS) | VAF 23/147 reads (16%) | called by mutect2, pindel, varscan2
- CHRNB4 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- CHST1 | c.422C>A p.P141Q | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CIC | c.1026del p.W343Gfs*7 | Frame Shift Del (DEL) | VAF 73/498 reads (15%) | called by mutect2, pindel, varscan2
- CLDN18 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 52/299 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- CLEC4M | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 22/499 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.792); called by muse, mutect2
- CNPY3 | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTNAP4 | c.3529G>A p.A1177T | Missense Mutation (SNP) | VAF 88/485 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- COL15A1 | c.2870T>C p.F957S | Missense Mutation (SNP) | VAF 54/376 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- COL1A1 | c.2680C>T p.P894S | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, mutect2
- COL22A1 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A3 | c.4594C>T p.R1532C | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.683); called by muse, varscan2
- COL8A2 | c.383del p.P128Qfs*109 | Frame Shift Del (DEL) | VAF 88/542 reads (16%) | called by pindel, varscan2
- CPEB4 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPO | c.1028A>G p.D343G | Missense Mutation (SNP) | VAF 22/529 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.086); called by muse, mutect2
- CROCC | c.1458del p.L487Sfs*37 | Frame Shift Del (DEL) | VAF 82/400 reads (21%) | called by mutect2, varscan2
- CSDE1 | c.1759G>T p.G587C (on ENST00000358528 / NM_001007553.3; = p.G556C on NM_007158.6) | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- CSPP1 | c.3032C>T p.A1011V (on ENST00000676605; = p.A970V on NM_024790.6) | Missense Mutation (SNP) | VAF 76/443 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CTNNB1 | c.57del p.A20Rfs*27 | Frame Shift Del (DEL) | VAF 61/439 reads (14%) | called by mutect2, pindel, varscan2
- CUL5 | c.1694del p.N565Ifs*18 | Frame Shift Del (DEL) | VAF 30/202 reads (15%) | called by mutect2, varscan2
- CXorf21 | c.217_218dup p.S73Rfs*63 | Frame Shift Ins (INS) | VAF 80/446 reads (18%) | called by mutect2, varscan2
- CYBRD1 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 60/331 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYHR1 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYLD | c.2165del p.N722Mfs*13 | Frame Shift Del (DEL) | VAF 26/192 reads (14%) | called by mutect2, varscan2
- CYTH3 | c.284A>T p.Q95L | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DBNL | c.800C>T p.A267V (on ENST00000448521 / NM_001014436.3; = p.A268V on NM_014063.7) | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- DBNL | c.995C>A p.A332D (on ENST00000448521 / NM_001014436.3; = p.A333D on NM_014063.7) | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- DCAF15 | c.1124del p.P375Lfs*45 | Frame Shift Del (DEL) | VAF 68/413 reads (16%) | called by mutect2, pindel, varscan2
- DCLK2 | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 61/376 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- DDX25 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 56/374 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEFB134 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DHX15 | c.1224del p.K408Nfs*10 | Frame Shift Del (DEL) | VAF 34/300 reads (11%) | called by mutect2, pindel, varscan2
- DKC1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DLC1 | c.2767T>C p.W923R (on ENST00000276297 / NM_001348081.2; = p.W486R on NM_006094.5) | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2
- DLGAP2 | c.4T>A p.S2T | Missense Mutation (SNP) | VAF 20/399 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.302); called by muse, mutect2
- DLGAP2 | c.919A>C p.S307R | Missense Mutation (SNP) | VAF 121/686 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DLL4 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 95/511 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- DLX6 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 144/473 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DMBT1 | c.5683T>A p.C1895S (on ENST00000338354 / NM_001377530.1; = p.C1138S on NM_004406.3) | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- DNAH5 | c.5563del p.I1855Sfs*16 | Frame Shift Del (DEL) | VAF 51/345 reads (15%) | called by mutect2, pindel, varscan2
- DNAH6 | c.617C>A p.P206H | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- DNAH7 | c.2162del p.K721Rfs*5 | Frame Shift Del (DEL) | VAF 23/191 reads (12%) | called by mutect2, pindel, varscan2
- DOCK10 | c.5012T>C p.M1671T | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- DOCK5 | c.374T>C p.I125T | Missense Mutation (SNP) | VAF 23/537 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2
- DOP1A | c.6084A>G p.I2028M | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.187); called by muse, mutect2
- DOP1B | c.1304T>C p.L435P | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DPP6 | c.972_977dup p.I325_M326insII (on ENST00000377770 / NM_001364500.2; = p.I263_M264insII on NM_001936.5) | In Frame Ins (INS) | VAF 36/305 reads (12%) | called by pindel, varscan2
- DYRK2 | c.1361del p.N454Ifs*3 (on ENST00000344096 / NM_006482.3; = p.N381Ifs*3 on NM_003583.4) | Frame Shift Del (DEL) | VAF 127/425 reads (30%) | called by mutect2, pindel, varscan2
- EBLN2 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.945); called by muse, mutect2
- EFR3B | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 67/347 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- EID1 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF3D | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- ELAC1 | c.722del p.K241Sfs*23 | Frame Shift Del (DEL) | VAF 45/318 reads (14%) | called by mutect2, pindel, varscan2
- EMC1 | c.1824del p.F608Lfs*7 | Frame Shift Del (DEL) | VAF 57/353 reads (16%) | called by mutect2, pindel, varscan2
- EMC2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- EMC4 | c.431del p.L144Wfs*22 | Frame Shift Del (DEL) | VAF 54/432 reads (13%) | called by mutect2, pindel, varscan2
- EN1 | c.317del p.F106Sfs*6 | Frame Shift Del (DEL) | VAF 60/390 reads (15%) | called by mutect2, pindel, varscan2
- ENO4 | c.222dup p.K75Efs*37 (on ENST00000622726; = p.K74Efs*37 on NM_001242699.2) | Frame Shift Ins (INS) | VAF 53/338 reads (16%) | called by mutect2, pindel, varscan2
- ENTPD7 | c.388del p.I130Sfs*23 | Frame Shift Del (DEL) | VAF 37/266 reads (14%) | called by mutect2, pindel, varscan2
- EP300 | c.7025dup p.Q2343Tfs*36 | Frame Shift Ins (INS) | VAF 80/494 reads (16%) | called by mutect2, pindel, varscan2
- EPM2AIP1 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 70/460 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPS8L3 | c.635A>G p.H212R | Missense Mutation (SNP) | VAF 78/422 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERBB4 | c.3530dup p.N1177Kfs*9 | Frame Shift Ins (INS) | VAF 53/317 reads (17%) | called by mutect2, pindel, varscan2
- ERCC3 | c.905T>A p.V302D | Missense Mutation (SNP) | VAF 60/373 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERCC6L | c.3119C>T p.T1040I | Missense Mutation (SNP) | VAF 15/404 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- ERLIN2 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 55/403 reads (14%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ERO1B | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- ESPN | c.2581C>T p.R861C | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- ETV6 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVI5L | c.1798G>A p.V600M | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.473); called by muse, mutect2
- FADD | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 58/358 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FADS2 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- FAM111B | c.847del p.I283Lfs*16 | Frame Shift Del (DEL) | VAF 28/198 reads (14%) | called by mutect2, varscan2
- FAM171A2 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- FAM187A | c.531del p.C178Vfs*63 | Frame Shift Del (DEL) | VAF 51/354 reads (14%) | called by mutect2, pindel, varscan2
- FAM20C | c.456del p.G153Afs*34 | Frame Shift Del (DEL) | VAF 52/428 reads (12%) | called by mutect2, varscan2
- FAM83H | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 60/400 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- FBLL1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.3); called by muse, mutect2, varscan2
- FBXO44 | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 89/493 reads (18%) | called by muse, mutect2, varscan2
- FCHO2 | c.1031A>T p.D344V | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FCHSD2 | c.860del p.L287Cfs*26 | Frame Shift Del (DEL) | VAF 62/285 reads (22%) | called by mutect2, pindel, varscan2
- FEM1A | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 90/412 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- FGF17 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 41/627 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- FLT4 | c.1267del p.Q423Rfs*70 | Frame Shift Del (DEL) | VAF 41/291 reads (14%) | called by mutect2, pindel, varscan2
- FOXA2 | c.349G>T p.A117S (on ENST00000377115 / NM_153675.3; = p.A123S on NM_021784.5) | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.225); called by muse, mutect2
- FOXD4 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 96/828 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- FUT8 | c.665G>A p.C222Y (on ENST00000360689 / NM_001371534.1; = p.C59Y on NM_004480.4) | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FZD8 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 59/382 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GFOD2 | c.695del p.G232Vfs*6 | Frame Shift Del (DEL) | VAF 59/440 reads (13%) | called by mutect2, pindel, varscan2
- GIPC1 | c.344del p.G115Afs*13 | Frame Shift Del (DEL) | VAF 65/480 reads (14%) | called by mutect2, pindel, varscan2
- GLP2R | c.93dup p.W32Lfs*39 | Frame Shift Ins (INS) | VAF 70/447 reads (16%) | called by mutect2, pindel, varscan2
- GLTPD2 | c.638A>G p.Q213R | Missense Mutation (SNP) | VAF 65/497 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- GOLGA3 | c.3971T>A p.L1324Q | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- GPC4 | c.674T>C p.L225S | Missense Mutation (SNP) | VAF 70/451 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR146 | c.1002G>T p.*334Yext*43 | Nonstop Mutation (SNP) | VAF 43/241 reads (18%) | called by muse, mutect2, varscan2
- GPR63 | c.218T>C p.F73S | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRID2IP | c.3549C>A p.F1183L | Missense Mutation (SNP) | VAF 13/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- HEATR5B | c.5509A>C p.S1837R | Missense Mutation (SNP) | VAF 74/401 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HECTD4 | c.8465A>G p.Y2822C | Missense Mutation (SNP) | VAF 54/406 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HECW2 | c.3547G>A p.A1183T | Missense Mutation (SNP) | VAF 57/368 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- HERC1 | c.13153del p.Q4385Sfs*5 | Frame Shift Del (DEL) | VAF 50/517 reads (10%) | called by mutect2, pindel
- HEXD | c.1459T>C p.*487Rext*45 (on ENST00000327949 / NM_001369487.1; = p.P516= on NM_173620.3) | Nonstop Mutation (SNP) | VAF 68/463 reads (15%) | called by muse, varscan2
- HIVEP3 | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 36/534 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.031); called by muse, mutect2
- HJV | c.487G>A p.G163R (on ENST00000336751 / NM_213653.4; = p.G50R on NM_145277.5) | Missense Mutation (SNP) | VAF 89/488 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- HLA-B | c.626del p.P209Qfs*5 | Frame Shift Del (DEL) | VAF 96/326 reads (29%) | called by mutect2, varscan2
- HPS4 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- HSPA4L | c.2505G>T p.E835D | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPH1 | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- HUS1 | c.517del p.M173* | Frame Shift Del (DEL) | VAF 38/221 reads (17%) | called by mutect2, pindel, varscan2
- ICE1 | c.634T>G p.W212G | Missense Mutation (SNP) | VAF 72/371 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IDE | c.2033C>A p.P678H | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IDE | c.110dup p.T38Dfs*7 | Frame Shift Ins (INS) | VAF 25/149 reads (17%) | called by mutect2, varscan2
- IDUA | c.1223C>G p.A408G | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by mutect2, varscan2
- IGLV2-11 | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 65/318 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IL17RC | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 111/478 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL31RA | c.1848C>G p.D616E | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2
- ILVBL | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 18/385 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.221); called by muse, mutect2
- INO80 | c.3029del p.L1010Cfs*29 | Frame Shift Del (DEL) | VAF 51/330 reads (15%) | called by mutect2, pindel, varscan2
- IPO5 | c.718C>T p.L240F | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- IPO5 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 19/247 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, mutect2
- IQSEC2 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 80/501 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IRF2BP1 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 45/453 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- IRX3 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 80/541 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- KAT7 | c.85A>C p.S29R | Missense Mutation (SNP) | VAF 72/408 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNB2 | c.2122A>G p.N708D | Missense Mutation (SNP) | VAF 20/520 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- KCNF1 | c.394A>C p.S132R | Missense Mutation (SNP) | VAF 65/429 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNS1 | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 19/486 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- KCTD10 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 60/488 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- KCTD21 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 88/491 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCTD9 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KIAA0319L | c.2532dup p.V845Cfs*14 | Frame Shift Ins (INS) | VAF 53/306 reads (17%) | called by mutect2, pindel, varscan2
- KIAA1210 | c.281G>C p.W94S | Missense Mutation (SNP) | VAF 50/333 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- KIF23 | c.2023C>T p.R675* | Nonsense Mutation (SNP) | VAF 50/297 reads (17%) | called by muse, mutect2, varscan2
- KIF2B | c.201del p.G68Afs*12 | Frame Shift Del (DEL) | VAF 64/408 reads (16%) | called by pindel, varscan2
- KIF5C | c.2445del p.S816Vfs*68 | Frame Shift Del (DEL) | VAF 54/364 reads (15%) | called by mutect2, pindel, varscan2
- KLF12 | c.197del p.P66Rfs*7 | Frame Shift Del (DEL) | VAF 79/400 reads (20%) | called by mutect2, pindel, varscan2
- KLF3 | c.318del p.K106Nfs*21 | Frame Shift Del (DEL) | VAF 66/459 reads (14%) | called by mutect2, pindel, varscan2
- KLHL32 | c.1120del p.R374Afs*8 | Frame Shift Del (DEL) | VAF 74/381 reads (19%) | called by mutect2, varscan2
- KLHL6 | c.1424del p.G475Efs*24 | Frame Shift Del (DEL) | VAF 50/367 reads (14%) | called by mutect2, pindel, varscan2
- KLK11 | c.208G>A p.A70T (on ENST00000594768 / NM_144947.3; = p.A38T on NM_006853.3) | Missense Mutation (SNP) | VAF 22/506 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- KMT2A | c.7616T>C p.L2539P | Missense Mutation (SNP) | VAF 61/369 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.14272T>C p.Y4758H | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- KNL1 | c.502A>G p.T168A (on ENST00000346991 / NM_170589.5; = p.T142A on NM_144508.5) | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KPNB1 | c.1525A>C p.K509Q | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT19 | c.880T>C p.S294P | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- LACTB2 | c.801dup p.L268Tfs*9 | Frame Shift Ins (INS) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- LAMA3 | c.7593G>T p.L2531F (on ENST00000313654 / NM_198129.4; = p.L922F on NM_000227.6) | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMB2 | c.3760T>G p.S1254A | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- LGMN | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LIMD1 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 82/454 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LMLN2 | c.1176G>T p.Q392H | Missense Mutation (SNP) | VAF 31/428 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); called by muse, mutect2
- LOXL1 | c.801del p.D268Tfs*159 | Frame Shift Del (DEL) | VAF 72/433 reads (17%) | called by mutect2, pindel, varscan2
- LPAR4 | c.120T>A p.N40K | Missense Mutation (SNP) | VAF 66/487 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- LRRC1 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- LRRC10B | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 88/436 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- LRRC63 | c.762A>G p.I254M | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- LRRC74A | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRTM3 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 70/397 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- LTB4R2 | c.1133del p.G378Vfs*47 (on ENST00000528054; = p.G347Vfs*47 on NM_019839.5) | Frame Shift Del (DEL) | VAF 59/371 reads (16%) | called by mutect2, varscan2
587 further variants in this file (262 protein-altering or splice-affecting, 277 silent, 48 other) are not listed here.
